Somatic mutation profile of tumor specimen TCGA-98-A53B-01A (aliquot TCGA-98-A53B-01A-11D-A25L-08) from TCGA case TCGA-98-A53B, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.5 years (25,390 days).
Specimen TCGA-98-A53B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29ffdf02-db41-4116-bd87-aa03c9916ace.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A53B-10A (Blood Derived Normal), aliquot TCGA-98-A53B-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68318e86-a176-4c8e-9318-12179c4778d4

The open-access MAF lists 158 somatic variants for this specimen: 126 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 30, Nonsense Mutation 12, Frame Shift Del 6, Frame Shift Ins 5, Splice Site 3, RNA 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FLCN | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs1555610290, CM166849, COSV99550279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1300-2A>G p.X434_splice (on ENST00000521381 / NM_181523.3; = p.X164_splice on NM_181504.4) | Splice Site (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); catalogued as rs1403833564, COSV57134758, COSV57136895; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2
- ABCA12 | c.6653T>G p.F2218C (on ENST00000272895 / NM_173076.3; = p.F1900C on NM_015657.3) | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV99789351; called by muse, mutect2, varscan2
- ACTRT1 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100947550, COSV100947755; called by muse, mutect2, varscan2
- ADHFE1 | c.501del p.I168Lfs*14 | Frame Shift Del (DEL) | VAF 41/195 reads (21%) | catalogued as rs1323475344; called by mutect2, pindel, varscan2
- ALOX12 | c.1915A>G p.T639A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.065); catalogued as COSV99277999; called by muse, mutect2, varscan2
- ANKRD17 | c.6724G>A p.A2242T | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as COSV100428873; called by muse, mutect2, varscan2
- AQP4 | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV101270500; called by muse, mutect2, varscan2
- ARID4B | c.2245A>G p.I749V | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99935380; called by muse, mutect2, varscan2
- ASNSD1 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.39); catalogued as COSV99641101; called by muse, mutect2, varscan2
- ATAD2 | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as COSV54879491, COSV99784401; called by muse, mutect2, varscan2
- ATAD2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV54885236, COSV99784402; called by muse, varscan2
- ATP10A | c.3029A>G p.Q1010R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791073; called by muse, mutect2, varscan2
- ATRNL1 | c.2923G>A p.G975S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100370098; called by muse, mutect2, varscan2
- BDKRB1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99387809; called by muse, mutect2, varscan2
- BIRC6 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70207321; called by muse, mutect2, varscan2
- BIRC6 | c.1998G>C p.Q666H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101428105; called by muse, mutect2, varscan2
- BIRC6 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV101428106; called by muse, mutect2
- CA5B | c.621C>T p.D207= | Splice Region (SNP) | VAF 19/50 reads (38%) | catalogued as rs1303393942, COSV59416868; called by muse, mutect2, varscan2
- CBLB | c.1349A>T p.D450V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99913174; called by muse, mutect2, varscan2
- CDC42EP4 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201845163, COSV59964142; called by muse, mutect2, varscan2
- CDHR2 | c.3281G>T p.R1094L | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV99991369; called by muse, mutect2, varscan2
- CEP68 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs764888119, COSV99560811; called by muse, mutect2, varscan2
- CLVS1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100369727; called by muse, mutect2, varscan2
- CNNM4 | c.1436A>G p.N479S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998646; called by muse, mutect2, varscan2
- COL11A1 | c.2621G>T p.G874V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100615919; called by muse, mutect2, varscan2
- CSMD3 | c.8947T>G p.W2983G (on ENST00000297405 / NM_001363185.1; = p.W2814G on NM_052900.3) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830716; called by muse, mutect2
- CXCL13 | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as rs1455250545, COSV54491989; called by muse, mutect2, varscan2
- DCSTAMP | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886390; called by muse, mutect2, varscan2
- DCUN1D4 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775715186, COSV58121806; called by muse, mutect2, varscan2
- DEUP1 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99976998; called by muse, mutect2, varscan2
- DNAJC10 | c.48G>T p.R16S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV99899113; called by muse, mutect2
- DSCAM | c.3577G>T p.A1193S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); catalogued as COSV101259722; called by muse, mutect2, varscan2
- DST | c.20150T>C p.L6717P (on ENST00000361203 / NM_001374722.1; = p.L4414P on NM_015548.5) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99754006; called by muse, mutect2, varscan2
- EN1 | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99727109; called by muse, mutect2
- FKBP3 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99360866; called by muse, mutect2, varscan2
- FRG2C | c.339C>A p.N113K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.833); catalogued as rs1448884735; called by muse, mutect2
- GFRA1 | c.625T>A p.Y209N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100815628; called by muse, mutect2, varscan2
- GPR149 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101078312; called by muse, mutect2, varscan2
- GREM1 | c.246T>A p.H82Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV100277881; called by muse, mutect2, varscan2
- GRIN2B | c.4364G>C p.C1455S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.229); catalogued as COSV101662995; called by muse, mutect2, varscan2
- H1-7 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100622184; called by muse, mutect2
- HIVEP2 | c.3302A>G p.Q1101R | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99172520; called by muse, mutect2, varscan2
- IFT140 | c.3744C>G p.I1248M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100794235, COSV63699249; called by muse, mutect2, varscan2
- IQCE | c.1632+1G>T p.X544_splice | Splice Site (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100383322; called by muse, mutect2, varscan2
- ITGA2B | c.1331C>A p.T444K | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99288731; called by muse, mutect2, varscan2
- ITIH5 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99904306; called by muse, mutect2, varscan2
- KCNG4 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100376980; called by muse, mutect2, varscan2
- KCTD16 | c.921C>A p.C307* | Nonsense Mutation (SNP) | VAF 42/87 reads (48%) | catalogued as COSV101568780; called by muse, mutect2, varscan2
- KDM5A | c.3776G>C p.R1259T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101238730, COSV101238868; called by muse, mutect2, varscan2
- KIAA1549L | c.647A>G p.N216S (on ENST00000321505; = p.N513S on NM_012194.3) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99683154; called by muse, mutect2, varscan2
- KIF13A | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99435206; called by muse, mutect2, varscan2
- KIF21A | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735387; called by muse, mutect2, varscan2
- KLB | c.800A>C p.Y267S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV99962067; called by muse, mutect2, varscan2
- KLHL15 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100044102; called by muse, mutect2, varscan2
- KLHL4 | c.1883del p.P628Lfs*29 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV64144217; called by mutect2, pindel, varscan2
- KMT2D | c.6958G>T p.E2320* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99979804; called by muse, mutect2, varscan2
- LRP1B | c.11066A>C p.H3689P | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.18); catalogued as COSV101255053; called by muse, mutect2, varscan2
- LRRTM1 | c.1079T>A p.F360Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.992); catalogued as rs1268475649, COSV99702209; called by muse, mutect2, varscan2
- MAP3K4 | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100815219; called by muse, mutect2, varscan2
- MTF1 | c.2215C>A p.L739M | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100888615; called by muse, mutect2, varscan2
- MYO1D | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100554033; called by muse, mutect2, varscan2
- MZB1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100136409; called by muse, mutect2, varscan2
- NOTCH1 | c.2774del p.G925Afs*254 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as COSV53030644; called by mutect2, pindel, varscan2
- NUP210L | c.122T>A p.V41E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99666255; called by muse, mutect2, varscan2
- OBSCN | c.15580A>T p.M5194L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99476021; called by muse, mutect2, varscan2
- OR52B4 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1481952727, COSV101281584; called by muse, mutect2, varscan2
- OR5F1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99558538; called by muse, mutect2, varscan2
- PCARE | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100527461; called by muse, mutect2, varscan2
- PCDH11X | c.1801G>T p.D601Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100010710; called by muse, mutect2, varscan2
- PCDHGA3 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs76939403, COSV99535199; called by muse, mutect2, varscan2
- PDILT | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.072); catalogued as COSV100199274; called by muse, mutect2, varscan2
- PHKA2 | c.759A>T p.K253N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101176920; called by muse, mutect2, varscan2
- PLCXD3 | c.226T>C p.W76R | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100125456, COSV100125557; called by muse, mutect2, varscan2
- PPP6R2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 48/180 reads (27%) | catalogued as COSV53293195, COSV99324087; called by muse, mutect2, varscan2
- PSMA4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.848); catalogued as COSV99245486; called by muse, mutect2
- RASA2 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53936978, COSV99655939; called by muse, mutect2, varscan2
- RASIP1 | c.2125A>T p.K709* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99710675; called by muse, varscan2
- RBMS3 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99820578; called by muse, mutect2, varscan2
- RELN | c.4631A>T p.H1544L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV100633217; called by muse, mutect2, varscan2
- ROS1 | c.2561G>A p.C854Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63859248; called by muse, mutect2, varscan2
- RPA4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100232180; called by mutect2, varscan2
- RPA4 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100232181; called by muse, mutect2, varscan2
- RRP12 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1158571485, COSV100213085; called by muse, mutect2, varscan2
- RTN1 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50722188, COSV99955251; called by muse, mutect2, varscan2
- RYR2 | c.9673G>T p.G3225C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100769347, COSV100769564; called by muse, mutect2, varscan2
- SCYL2 | c.2085G>T p.K695N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100675135; called by muse, mutect2, varscan2
- SDR42E1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as COSV100200688; called by muse, mutect2, varscan2
- SHPRH | c.4030G>T p.A1344S (on ENST00000275233 / NM_001042683.3; = p.A1348S on NM_173082.3) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV99261818; called by muse, mutect2, varscan2
- SIPA1L3 | c.4427A>G p.K1476R | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.445); catalogued as COSV99728171; called by muse, mutect2, varscan2
- SLC15A4 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99903514; called by muse, mutect2, varscan2
- SLC2A3 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV99306440; called by muse, mutect2, varscan2
- SLC36A4 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs757180258, COSV100419311; called by muse, mutect2, varscan2
- SNAI3 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100178821; called by muse, mutect2, varscan2
- SOX8 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53509323, COSV99559206; called by muse, mutect2, varscan2
- STAB1 | c.6713C>T p.A2238V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100194733; called by muse, mutect2, varscan2
- SUPT16H | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359778; called by muse, mutect2, varscan2
- SYNE2 | c.4261G>T p.E1421* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100647328; called by muse, mutect2, varscan2
- TMEM132D | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 50/198 reads (25%) | catalogued as COSV101397207; called by muse, mutect2, varscan2
- TNR | c.2805C>A p.S935R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54898167, COSV99688832; called by muse, mutect2, varscan2
- TRPV1 | c.2323A>C p.S775R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV99439197; called by muse, varscan2
- TSHZ3 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1056934810, COSV53663033; called by muse, mutect2, varscan2
- TTN | c.97061C>A p.A32354D (on ENST00000591111; = p.A24930D on NM_003319.4) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | PolyPhen probably damaging (0.966); catalogued as COSV100604531; called by muse, mutect2, varscan2
- TTN | c.16214C>A p.A5405D (on ENST00000591111; = p.A4478D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | PolyPhen possibly damaging (0.51); catalogued as COSV100604533; called by muse, mutect2
- TXK | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570769288, COSV99972346; called by muse, mutect2, varscan2
- UBN1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99277775; called by muse, mutect2, varscan2
- UBN1 | c.1431G>A p.K477= | Splice Region (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99277777; called by muse, mutect2, varscan2
- USP17L2 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100414558; called by muse, mutect2, varscan2
- WNT2 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99625931; called by muse, mutect2
- ZEB2 | c.2156G>C p.S719T | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100355670; called by muse, mutect2, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ZNF569 | c.401A>C p.H134P | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV100386385; called by muse, mutect2, varscan2
- ZNF75D | c.61del p.E21Rfs*6 | Frame Shift Del (DEL) | VAF 59/134 reads (44%) | catalogued as COSV66132475; called by mutect2, pindel, varscan2
- ZUP1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs531039256, COSV100885062; called by muse, mutect2, varscan2
- ABCC3 | c.4500dup p.V1501Sfs*3 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- ATF7IP2 | c.882del p.K295Nfs*3 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- DCDC1 | c.4173del p.M1392* (on ENST00000597505 / NM_001367979.1; = p.M499* on NM_020869.3) | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.7741G>A p.G2581R | Missense Mutation (SNP) | VAF 71/495 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); called by muse, mutect2
- GDF2 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GPAM | c.1802dup p.P602Sfs*3 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- LRRC31 | c.1625dup p.S543Kfs*5 | Frame Shift Ins (INS) | VAF 46/119 reads (39%) | called by mutect2, pindel, varscan2
- MYO3A | c.3037dup p.R1013Pfs*5 | Frame Shift Ins (INS) | VAF 37/250 reads (15%) | called by mutect2, pindel, varscan2
- TRAV25 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRGV3 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM32 | c.1539T>A p.A513= | Silent (SNP) | VAF 64/197 reads (32%) | catalogued as COSV101165348; called by muse, mutect2, varscan2
- APOBEC1 | c.6T>C p.T2= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99981050; called by muse, mutect2, varscan2
- BIRC6 | c.1875G>A p.R625= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs761513610, COSV101428104; called by muse, mutect2, varscan2
- CCDC63 | c.267T>C p.S89= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100370291; called by muse, mutect2, varscan2
- COL22A1 | c.4767A>G p.P1589= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100277588; called by muse, mutect2, varscan2
- CRMP1 | c.660C>T p.P220= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs369101516; called by muse, mutect2, varscan2
- CXCL2 | c.258C>G p.L86= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99933194; called by muse, mutect2
- DIAPH3 | c.2601C>G p.L867= (on ENST00000400324 / NM_001042517.2; = p.L604= on NM_030932.3) | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99933195; called by muse, mutect2, varscan2
- F11 | c.1779G>T p.T593= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV53001891, COSV99250762; called by muse, mutect2, varscan2
- FAT2 | c.11997A>G p.G3999= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV99942353; called by muse, mutect2, varscan2
- FAT3 | c.9918G>A p.R3306= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- GCN1 | c.4263A>C p.A1421= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100324963; called by muse, mutect2, varscan2
- GOLGB1 | c.1839A>T p.V613= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as COSV100510624; called by muse, mutect2, varscan2
- GRM8 | c.417C>A p.P139= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100281933; called by muse, mutect2, varscan2
- KMT2D | c.6957G>C p.L2319= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99979807; called by muse, mutect2, varscan2
- LRP1B | c.12585G>T p.V4195= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV101255052; called by muse, mutect2, varscan2
- LRP1B | c.10734C>T p.C3578= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV101255056; called by muse, mutect2, varscan2
- OR2T4 | c.225T>C p.A75= | Silent (SNP) | VAF 56/296 reads (19%) | catalogued as rs1168946006, COSV100822446; called by muse, mutect2, varscan2
- PPP1R32 | c.24G>A p.G8= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1443669008, COSV100087757; called by mutect2, varscan2
- PSG9 | c.618T>C p.G206= | Silent (SNP) | VAF 42/436 reads (10%) | catalogued as COSV99392167; called by muse, mutect2
- PXDN | c.3588G>A p.E1196= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as COSV99413024; called by muse, mutect2, varscan2
- RASAL1 | c.2394C>T p.A798= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs537928112, COSV99921598; called by muse, mutect2
- RO60 | c.987A>G p.E329= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100814353; called by muse, mutect2, varscan2
- SIGLEC1 | c.219G>A p.S73= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs138966589; called by muse, mutect2, varscan2
- SLC30A9 | c.1077A>G p.T359= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100048104; called by muse, mutect2, varscan2
- TACC2 | c.7530C>T p.F2510= (on ENST00000334433; = p.F588= on NM_006997.4) | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV99586880; called by muse, mutect2, varscan2
- ZEB2 | c.960C>T p.S320= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1433021360, COSV100355672; called by mutect2, varscan2
- ZNF362 | c.501C>T p.I167= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs372351139; called by muse, mutect2, varscan2
- ZNF605 | c.1854A>T p.G618= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100053528; called by muse, mutect2, varscan2
- ZNF75A | c.890G>A p.*297= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV73039688; called by muse, mutect2, varscan2
- MALAT1 | n.75dup | RNA (INS) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- OR2W5 | n.600T>C | RNA (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
